Gene-level copy-number profile of tumor specimen ALCH-B4XR-TTP1-A from ALCHEMIST case ALCH-B4XR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 76.7 years (28,010 days).
Specimen ALCH-B4XR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a705a06-8f05-4e7c-9242-5e89bf055c19.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4XR-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/bcb6ed9d-4060-4888-87b7-0562830007d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 4,449; copy number 2: 40,264; copy number 3: 10,005; copy number 4: 3,324; copy number 5: 272; copy number 6: 40; copy number 7: 2; copy number 14: 3; copy number 19: 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:944,203–959,309, 1 gene (within-gene range 0–2): NOC2L.
- chr1:16,974,502–17,011,928, 5 genes: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3.
- chr2:232,343,116–232,351,309, 2 genes (within-gene range 0–2): NRBF2P6, ECEL1P3.
- chr6:30,890,883–30,890,972, 1 gene (within-gene range 0–3): MIR4640.
- chr6:168,053,166–168,101,511, 1 gene: FRMD1.
- chr7:74,453,790–74,602,605, 2 genes (within-gene range 0–3): GTF2IRD1, RNA5SP233.
- chr15:23,430,839–23,435,212, 1 gene: HERC2P6.
- chr15:75,624,793–75,662,301, 6 genes (within-gene range 0–2): AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33.
- chr16:83,929,796–83,931,223, 1 gene (within-gene range 0–2): AC009119.2.
- chr17:2,692,861–2,692,919, 1 gene: MIR6776.
- chr18:79,395,856–79,589,010, 7 genes: NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC068473.3.
- chr22:29,720,003–29,731,833, 1 gene (within-gene range 0–2): CABP7.
- chr22:45,875,932–45,891,438, 2 genes: BX324167.2, BX324167.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 318 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:212,225,278–212,414,901, 8 genes, copy number 5: LINC02608, PPP2R5A, AL360091.2, AL360091.3, RPL23AP18, SNORA16B, AL360091.1, PACC1.
- chr7:117,287,120–117,715,971, 1 gene, copy number 5 (within-gene range 2–5): CFTR.
- chr7:117,560,733–118,204,035, 7 genes, copy number 5: CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8.
- chr7:130,668,643–134,579,875, 55 genes, copy number 5 (within-gene range 2–5): TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1, AC105443.1, PLXNA4, AC018643.1, AC011625.1, FLJ40288, AC009365.1, AC009365.2, CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133, AC083875.1, COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15.
- chr7:137,344,930–142,793,368, 189 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr7:142,801,041–142,802,748, 1 gene, copy number 5: TRBC2.
- chr9:41,479,960–41,573,606, 3 genes, copy number 5: AL354718.1, AL591926.3, SNORA70.
- chr9:64,621,560–64,811,429, 4 genes, copy number 5–14: AQP7P2, AL445665.1, BMS1P11, BNIP3P4.
- chr14:18,333,726–18,341,859, 1 gene, copy number 19: CR383658.1.
- chr14:18,418,775–18,419,273, 1 gene, copy number 6: BNIP3P6.
- chr16:28,179,098–28,183,430, 2 genes, copy number 5: AC136611.1, RNY1P10.
- chr17:77,959,240–78,108,835, 4 genes, copy number 5–6: TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P.
- chr19:32,345,594–32,587,453, 4 genes, copy number 5: ZNF507, AC007773.1, DPY19L3, PDCD5.
- chr19:35,137,645–35,601,596, 35 genes, copy number 6 (within-gene range 4–6): AC020907.5, FXYD1, AC020907.2, FXYD7, FXYD5, FAM187B, FAM187B2P, LSR, AC002128.2, AC002128.1, USF2, HAMP, MAG, CD22, U62631.1, MIR5196, FFAR1, FFAR3, GPR42, EEF1A1P7, LINC01531, AC002511.3, RN7SL491P, AC002511.2, AC002511.1, FFAR2, KRTDAP, DMKN, SBSN, GAPDHS, TMEM147-AS1, TMEM147, ATP4A, AD000090.1, LINC01766.
- chr21:45,073,853–45,226,560, 1 gene, copy number 6 (within-gene range 3–6): ADARB1.
- chr21:46,458,891–46,570,015, 1 gene, copy number 7 (within-gene range 3–7): DIP2A.
- chr21:46,525,618–46,525,722, 1 gene, copy number 7: RNU6-396P.

Autosomal genes at a single copy (total copy number 1): 4,449. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
